Gene-level copy-number profile of tumor specimen HTMCP-03-06-02076-01A from CGCI case HTMCP-03-06-02076, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 32.8 years (11,983 days).
Specimen HTMCP-03-06-02076-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 92cadd1c-aae1-42a1-8d3f-e64aefdb0799.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02076-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/3f87ee5e-69f9-4262-99e3-7452e403829a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,839; copy number 2: 48,874; copy number 3: 5,286; copy number 4: 184; copy number 5: 193; copy number 6: 7; copy number 7: 13.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes (within-gene range 0–1): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 213 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:99,020,949–107,666,779, 110 genes, copy number 5 (broad region; genes not listed).
- chr16:32,600,299–32,615,639, 1 gene, copy number 7: AC137800.1.
- chr19:11,466,240–12,758,458, 95 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:24,004,358–24,163,425, 7 genes, copy number 6: RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.

Autosomal genes at a single copy (total copy number 1): 3,722. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
